MMRF case MMRF_2532 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7da8f33a-e801-40b6-b2e5-431f2a59232f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.8 years (26,940 days); ISS stage: I; Days to last known disease status: 708 days (1.9 years); Days to last follow up: 708 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 81 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 71 days; Days to treatment end: 81 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 133 days; Days to treatment end: 133 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 135 days; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 605 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 5.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.48 mg/dL; Immunoglobulin G 68.4 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 3.33 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.41 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.55 mmol/L; Albumin 35 g/L; Total Protein 10.8 g/dL; Glucose 6.82 mmol/L; C-Reactive Protein 0.034 mg/dL.
- Day 71 (ECOG 1): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 5.75 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 1.88 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.51 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.5 mmol/L.
- Day 155 (ECOG 1): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 5.75 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 1.89 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.19 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 9.52 mmol/L.
- Day 281 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.31 mg/dL; Immunoglobulin G 8.12 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 2.14 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.44 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.06 mmol/L.
- Day 365 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.01 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.24 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.38 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 7.15 mmol/L.
- Day 449 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.83 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.68 µg/mL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.03 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 7.43 mmol/L.
- Day 540: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 2.4 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.27 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 6 mmol/L.
- Day 603: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 2.5 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.54 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 6 mmol/L.
- Day 708: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.63 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.02 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5.61 mmol/L.

Other clinical attributes
- Day 1: Weight: 78 kg; Height: 174 cm.

Biospecimens (2 samples)
- Sample MMRF_2532_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2532_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
